Somatic mutation profile of tumor specimen 0DNUGS from CCDI case PBCBVD, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.5 years (5,300 days).
Specimen 0DNUGS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3a42341a-8114-4ccb-a2a3-47fc0e79483e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNUGA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29fdc18e-81eb-48ed-9a9a-547fa101adba

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LRP1B | c.4661G>A p.C1554Y | Missense Mutation (SNP) | VAF 59/1077 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67196669; called by muse, mutect2
- TEX15 | c.5149C>T p.R1717* (on ENST00000256246; = p.R2100* on NM_001350162.2) | Nonsense Mutation (SNP) | VAF 42/1075 reads (4%) | catalogued as rs1324219823, COSV56341451; called by muse, mutect2
- RMI1 | c.-9T>A | 5'UTR (SNP) | VAF 32/234 reads (14%) | called by muse, varscan2
